Somatic mutation profile of tumor specimen TCGA-AA-A02E-01A (aliquot TCGA-AA-A02E-01A-01W-A00E-09) from TCGA case TCGA-AA-A02E, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.8 years (30,256 days).
Specimen TCGA-AA-A02E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0130e3e9-a32d-4b2d-a17d-73e107840fc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02E-10A (Blood Derived Normal), aliquot TCGA-AA-A02E-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c6959c3-037c-41cc-bb2d-3757fae11675

The open-access MAF lists 172 somatic variants for this specimen: 130 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 39, Nonsense Mutation 5, In Frame Del 4, Splice Site 4, Frame Shift Del 3, Frame Shift Ins 3, Nonstop Mutation 1, 3'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 133/311 reads (43%) | catalogued as rs137852216, CM090021, COSV57654256, COSV57668550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/49 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 100/237 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 37/56 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747342068, CM086989, CM973641, COSV52689323, COSV52708494, COSV52979406, COSV53353999; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV58155893; called by muse, mutect2, varscan2
- ADAMTS12 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.669); catalogued as rs765907510; called by muse, mutect2, varscan2
- ADGRF5 | c.505+2T>G p.X169_splice | Splice Site (SNP) | VAF 44/305 reads (14%) | catalogued as COSV51937089; called by muse, mutect2, varscan2
- ADGRG4 | c.5258C>A p.P1753H | Missense Mutation (SNP) | VAF 42/1596 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV54951970; called by muse, mutect2
- AFTPH | c.2692G>A p.E898K (on ENST00000238855 / NM_203437.3; = p.E871K on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 204/530 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs772490202; called by muse, mutect2, varscan2
- AGPAT4 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs141441479; called by muse, mutect2, varscan2
- APC | c.2546del p.D849Vfs*12 | Frame Shift Del (DEL) | VAF 187/379 reads (49%) | catalogued as CD011084; called by mutect2, pindel, varscan2
- AXL | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs1258438798; called by muse, mutect2, varscan2
- C1orf127 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs759814756, COSV65436965; called by muse, mutect2
- CA8 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 112/339 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58772998; called by muse, mutect2, varscan2
- CASP8 | c.1309G>A p.D437N (on ENST00000432109 / NM_033355.3; = p.D454N on NM_001228.4) | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs746684914, COSV51849146; called by muse, mutect2, varscan2
- CCR2 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 520/1302 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as rs771654222, COSV52748597; called by muse, mutect2, varscan2
- CDH12 | c.400A>C p.I134L | Missense Mutation (SNP) | VAF 300/951 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1486652242; called by muse, mutect2, varscan2
- CDH7 | c.1835C>A p.A612D | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs752090043; called by muse, mutect2, varscan2
- CDKL2 | c.222A>C p.K74N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1378054588; called by muse, mutect2, varscan2
- CER1 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 198/481 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV66603184, COSV66603938; called by muse, mutect2, varscan2
- CSMD3 | c.768T>G p.S256R | Missense Mutation (SNP) | VAF 303/560 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV52295814; called by muse, mutect2, varscan2
- DCAF16 | c.412C>G p.H138D | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV66384068; called by muse, mutect2, varscan2
- DCUN1D3 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 123/374 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs774666903; called by muse, mutect2
- DSCAML1 | c.5737G>A p.D1913N (on ENST00000321322; = p.D1853N on NM_020693.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs376765047; called by muse, mutect2, varscan2
- EEF1A1 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs918193857, COSV58549585; called by muse, mutect2, varscan2
- EPHA5 | c.2905T>G p.S969A | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99901659; called by muse, mutect2
- FGF5 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs184034246; called by muse, mutect2
- FOXA2 | c.590G>A p.R197Q (on ENST00000377115 / NM_153675.3; = p.R203Q on NM_021784.5) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs372773557, COSV101008356; called by muse, mutect2, varscan2
- FSHR | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 143/367 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV58618791, COSV58620376, COSV58630781; called by muse, mutect2, varscan2
- GABBR1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV63542715; called by muse, mutect2, varscan2
- GFM2 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 172/667 reads (26%) | catalogued as COSV54667686; called by muse, mutect2, varscan2
- GLI1 | c.671_672dup p.E225Rfs*56 | Frame Shift Ins (INS) | VAF 30/62 reads (48%) | catalogued as rs1566559797; called by mutect2, varscan2
- GPR85 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 149/273 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV51783788; called by muse, mutect2, varscan2
- GRIA1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759117420, COSV53589188; called by muse, mutect2, varscan2
- HERC2 | c.13046G>A p.R4349H | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555401035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMGN5 | c.113G>T p.R38I | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63916947; called by muse, mutect2, varscan2
- KIAA1210 | c.2194A>C p.K732Q | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs771437164; called by muse, mutect2, varscan2
- KLF11 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs541774526, COSV59940424; called by muse, mutect2, varscan2
- KRT73 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1210935768, COSV59837684, COSV99988492; called by muse, mutect2, varscan2
- LRP1B | c.5093T>G p.L1698R | Missense Mutation (SNP) | VAF 93/563 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67189309; called by muse, mutect2, varscan2
- MYH1 | c.3130C>T p.Q1044* | Nonsense Mutation (SNP) | VAF 68/102 reads (67%) | catalogued as rs914529134; called by muse, mutect2, varscan2
- NALCN | c.4468G>A p.V1490I | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs770660098, COSV51919080; called by muse, mutect2
- NEGR1 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60864850; called by muse, mutect2, varscan2
- NHLRC2 | c.1456dup p.R486Kfs*15 | Frame Shift Ins (INS) | VAF 104/587 reads (18%) | catalogued as rs1054030952; called by mutect2, varscan2
- NMT1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs867687573; called by muse, mutect2, varscan2
- OLFML2B | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs142774017; called by muse, mutect2, varscan2
- OR2W3 | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1371094257; called by muse, mutect2, varscan2
- OR8K3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 25/790 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57131499; called by muse, mutect2
- PCDHB8 | c.1186T>A p.S396T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as rs782602946; called by muse, mutect2, varscan2
- PDHA2 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99756366; called by muse, mutect2, varscan2
- PPP2R2C | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs747639231, COSV59442406; called by muse, mutect2, varscan2
- PRKDC | c.12145A>T p.R4049* | Nonsense Mutation (SNP) | VAF 31/129 reads (24%) | catalogued as COSV58051481; called by muse, mutect2, varscan2
- RFPL1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 275/715 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1237681316, COSV62978441; called by muse, mutect2, varscan2
- SAGE1 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 470/807 reads (58%) | SIFT tolerated (0.73); PolyPhen benign (0.184); catalogued as rs782691323, COSV61012032; called by muse, mutect2, varscan2
- SIX4 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as rs1012956373, COSV53669533; called by muse, mutect2
- SMAD4 | c.1256G>C p.G419A | Missense Mutation (SNP) | VAF 134/219 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV61685351, COSV61686692; called by muse, mutect2, varscan2
- SPAG17 | c.5185del p.T1729Lfs*21 | Frame Shift Del (DEL) | VAF 118/292 reads (40%) | catalogued as rs1400383672, COSV60464528; called by mutect2, pindel, varscan2
- SPHKAP | c.3020C>T p.T1007M | Missense Mutation (SNP) | VAF 141/249 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752182241, COSV60868700; called by muse, mutect2, varscan2
- SPOPL | c.1043C>A p.T348N | Missense Mutation (SNP) | VAF 826/2061 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54513354; called by muse, mutect2, varscan2
- STAG3 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1050008131, COSV100425508; called by muse, mutect2, varscan2
- STK10 | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs751412361; called by muse, mutect2, varscan2
- SYTL5 | c.1962G>T p.K654N | Missense Mutation (SNP) | VAF 177/371 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99937533; called by muse, mutect2, varscan2
- TNR | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200243334, COSV54917465, COSV99687753; called by muse, mutect2, varscan2
- TRIM33 | c.1928C>T p.T643M | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760094981, COSV61822532; called by muse, mutect2, varscan2
- TRPC4 | c.2212-1G>C p.X738_splice (on ENST00000379705 / NM_016179.4; = p.X743_splice on NM_003306.3) | Splice Site (SNP) | VAF 105/372 reads (28%) | catalogued as COSV100155971, COSV58999504; called by muse, mutect2, varscan2
- TSHZ3 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as rs775547291, COSV99550738, COSV99551172; called by muse, mutect2, varscan2
- TTN | c.56152A>G p.S18718G (on ENST00000591111; = p.S11294G on NM_003319.4) | Missense Mutation (SNP) | VAF 53/311 reads (17%) | PolyPhen benign (0.15); catalogued as rs762408700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B10 | c.1440C>A p.H480Q | Missense Mutation (SNP) | VAF 227/933 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.279); catalogued as COSV55320220; called by muse, mutect2, varscan2
- UNC5C | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV71662304; called by muse, mutect2, varscan2
- ZFHX4 | c.7819C>T p.R2607C | Missense Mutation (SNP) | VAF 200/369 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309561230, COSV50480018, COSV50538350, COSV99265401; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 161/423 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs780858349; called by muse, mutect2, varscan2
- ZNF526 | c.1952A>C p.Q651P | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV55899216; called by muse, mutect2, varscan2
- ZNF597 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1184092041; called by muse, mutect2
- ZNF835 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV73379338; called by muse, mutect2, varscan2
- ALOX5 | c.1151_1153del p.Y384_R385delinsC | In Frame Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel*
- ARHGAP21 | c.2434A>G p.S812G | Missense Mutation (SNP) | VAF 185/472 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPH | c.1479T>A p.H493Q | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP12A | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); called by muse, mutect2
- ATP2B1 | c.2187A>T p.E729D | Missense Mutation (SNP) | VAF 327/1351 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRNL1 | c.550_561del p.S184_A187del | In Frame Del (DEL) | VAF 57/183 reads (31%) | called by mutect2, pindel, varscan2
- CARMIL1 | c.2753A>C p.K918T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CATSPERE | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 80/928 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC127 | c.385C>A p.Q129K | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA2 | c.2088G>T p.K696N | Missense Mutation (SNP) | VAF 155/399 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CYLD | c.1973A>G p.K658R | Missense Mutation (SNP) | VAF 238/575 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- DKK4 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DMXL1 | c.5081T>A p.F1694Y | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP22 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DYNC2H1 | c.6638T>C p.F2213S | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAT4 | c.8785A>G p.I2929V | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FBXO21 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FBXO30 | c.1829A>T p.N610I | Missense Mutation (SNP) | VAF 242/827 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FNDC3B | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 151/417 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- FRMPD1 | c.4157A>G p.H1386R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLS2 | c.1460_1461del p.V487Gfs*9 | Frame Shift Del (DEL) | VAF 56/141 reads (40%) | called by pindel, varscan2
- GRIK2 | c.1805T>A p.V602E | Missense Mutation (SNP) | VAF 185/633 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GUCY1B1 | c.570T>G p.D190E | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HEPH | c.3145A>G p.T1049A (on ENST00000343002; = p.T782A on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/440 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IL7R | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 202/358 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- IMP3 | c.538T>G p.F180V | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- LRRIQ1 | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- MASP1 | c.2099G>T p.*700Lext*94 | Nonstop Mutation (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- MUC16 | c.13171A>C p.T4391P | Missense Mutation (SNP) | VAF 32/890 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- MYH8 | c.905-2A>T p.X302_splice | Splice Site (SNP) | VAF 36/663 reads (5%) | called by muse, mutect2
- MYL9 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- NCAM2 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 132/322 reads (41%) | called by muse, mutect2, varscan2
- NRAP | c.4785G>C p.K1595N (on ENST00000359988 / NM_001322945.2; = p.K1560N on NM_006175.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PCDH17 | c.2495G>A p.C832Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PRMT5 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PROSER1 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 607/844 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RFX6 | c.1756_1794del p.S586_T598del | In Frame Del (DEL) | VAF 64/480 reads (13%) | called by mutect2, pindel
- SERPINB3 | c.866T>G p.V289G | Missense Mutation (SNP) | VAF 254/370 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SEZ6L2 | c.1637G>T p.S546I (on ENST00000308713 / NM_001114099.3; = p.S476I on NM_012410.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SH3TC2 | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SPIN4 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SYNE1 | c.8569C>T p.H2857Y (on ENST00000367255 / NM_182961.4; = p.H2864Y on NM_033071.3) | Missense Mutation (SNP) | VAF 122/739 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- SYNE1 | c.3728_3729insC p.S1244Ffs*10 (on ENST00000367255 / NM_182961.4; = p.S1251Ffs*10 on NM_033071.3) | Frame Shift Ins (INS) | VAF 30/191 reads (16%) | called by mutect2, pindel, varscan2
- TBC1D25 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- TECTA | c.4290T>A p.D1430E | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TET1 | c.2761C>A p.Q921K | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2
- UBASH3B | c.1813-2A>T p.X605_splice | Splice Site (SNP) | VAF 125/244 reads (51%) | called by muse, mutect2, varscan2
- USP33 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 166/561 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- UTP4 | c.1291T>C p.S431P | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- YARS2 | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2
- ZBBX | c.2172A>C p.E724D | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZBTB49 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIC1 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- ZIM2 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF320 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 52/1148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF684 | c.693_695del p.V232del | In Frame Del (DEL) | VAF 137/282 reads (49%) | called by mutect2, pindel, varscan2
- ADRA1B | c.150G>A p.L50= | Silent (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- ATP12A | c.2004G>A p.E668= | Silent (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- CASS4 | c.2100G>A p.A700= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as rs143052505; called by muse, mutect2, varscan2
- CCDC60 | c.669C>A p.P223= | Silent (SNP) | VAF 169/310 reads (55%) | called by muse, mutect2, varscan2
- CHD9 | c.1554A>G p.E518= | Silent (SNP) | VAF 124/318 reads (39%) | catalogued as rs780864718; called by muse, mutect2, varscan2
- COL6A3 | c.462G>A p.S154= | Silent (SNP) | VAF 65/240 reads (27%) | catalogued as rs773051161; called by muse, mutect2, varscan2
- DCLK3 | c.45A>T p.V15= | Silent (SNP) | VAF 127/347 reads (37%) | called by muse, mutect2, varscan2
- DIP2B | c.3273C>A p.V1091= | Silent (SNP) | VAF 63/478 reads (13%) | called by muse, mutect2, varscan2
- DLG3 | c.1794C>T p.D598= | Silent (SNP) | VAF 36/212 reads (17%) | catalogued as rs1015617791; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLGAP2 | c.1263C>T p.T421= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs374538901; called by muse, mutect2, varscan2
- FLG | c.6426G>A p.P2142= | Silent (SNP) | VAF 182/641 reads (28%) | catalogued as rs573959413, COSV64240432; called by muse, mutect2, varscan2
- GIMAP5 | c.114C>T p.C38= | Silent (SNP) | VAF 139/364 reads (38%) | catalogued as rs149695569, COSV57529925; called by muse, mutect2, varscan2
- GRM1 | c.2619C>T p.L873= | Silent (SNP) | VAF 110/394 reads (28%) | catalogued as rs765450864, COSV51110096; called by muse, mutect2, varscan2
- HIPK1 | c.90C>T p.G30= | Silent (SNP) | VAF 617/1994 reads (31%) | catalogued as COSV65784472; called by muse, varscan2
- HTR1A | c.99C>T p.V33= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs775530992; called by muse, mutect2, varscan2
- KMT2D | c.6933C>T p.S2311= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV56437913; called by muse, mutect2, varscan2
- KRTAP24-1 | c.372C>A p.T124= | Silent (SNP) | VAF 11/311 reads (4%) | called by muse, mutect2
- LHX9 | c.495C>T p.N165= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- MACF1 | c.4035T>C p.T1345= | Silent (SNP) | VAF 10/334 reads (3%) | called by muse, mutect2
- MACF1 | c.22122C>A p.T7374= (on ENST00000372915; = p.T5419= on NM_012090.5) | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- NOMO3 | c.360G>A p.G120= | Silent (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- OR4F4 | c.822C>T p.L274= | Silent (SNP) | VAF 72/2729 reads (3%) | called by muse, mutect2
- OR6B3 | c.690G>A p.S230= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs766977226; called by muse, mutect2, varscan2
- OR8H1 | c.921A>G p.R307= | Silent (SNP) | VAF 155/372 reads (42%) | catalogued as rs774300048, COSV57293682; called by muse, mutect2, varscan2
- PCDHA6 | c.1671C>T p.D557= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV65341441; called by muse, mutect2, varscan2
- PCDHA8 | c.1980C>T p.T660= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs138591837; called by muse, mutect2, varscan2
- PCDHGA5 | c.1587G>A p.Q529= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV53943914; called by muse, mutect2, varscan2
- PPP1R16B | c.1200C>A p.P400= | Silent (SNP) | VAF 75/114 reads (66%) | called by muse, mutect2, varscan2
- SEC14L5 | c.459C>T p.T153= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs377449115; called by muse, mutect2, varscan2
- SLC2A10 | c.552C>T p.F184= | Silent (SNP) | VAF 4/104 reads (4%) | catalogued as rs1196068646, COSV63715543; called by muse, mutect2
- SLC8A1 | c.1365T>C p.S455= | Silent (SNP) | VAF 54/421 reads (13%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.153G>A p.S51= | Silent (SNP) | VAF 187/460 reads (41%) | catalogued as rs774360466, COSV61195517; called by muse, mutect2, varscan2
- SYNE1 | c.8568C>A p.L2856= (on ENST00000367255 / NM_182961.4; = p.L2863= on NM_033071.3) | Silent (SNP) | VAF 124/745 reads (17%) | called by muse, mutect2, varscan2
- SYNE1 | c.7155G>T p.L2385= (on ENST00000367255 / NM_182961.4; = p.L2392= on NM_033071.3) | Silent (SNP) | VAF 18/646 reads (3%) | called by muse, mutect2
- TENT5D | c.1011T>C p.N337= | Silent (SNP) | VAF 198/465 reads (43%) | called by muse, mutect2, varscan2
- UBR4 | c.1158C>T p.D386= | Silent (SNP) | VAF 93/309 reads (30%) | called by muse, mutect2, varscan2
- ZIM2 | c.1149T>G p.T383= | Silent (SNP) | VAF 195/323 reads (60%) | catalogued as COSV55633455; called by muse, mutect2, varscan2
- ZNF146 | c.135A>G p.E45= | Silent (SNP) | VAF 161/229 reads (70%) | catalogued as rs576184561, COSV61931779; called by muse, mutect2, varscan2
- ZNF217 | c.2496C>T p.A832= | Silent (SNP) | VAF 151/410 reads (37%) | catalogued as rs540656868, COSV56596762; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668361 T>C | 5'Flank (SNP) | VAF 87/128 reads (68%) | catalogued as rs781169829; called by muse, mutect2, varscan2
- EI24P4 | n.919G>C | RNA (SNP) | VAF 472/1385 reads (34%) | called by muse, mutect2, varscan2
- SPINK13 | c.*2G>A | 3'UTR (SNP) | VAF 121/268 reads (45%) | called by muse, mutect2, varscan2
